Somatic mutation profile of tumor specimen 0DUB85 from CCDI case PBCKAN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,289 days).
Specimen 0DUB85: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 70357b03-22d0-47f9-81c6-093d96b777fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUB64 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a42f1142-bf83-4334-8be0-6da1147feb51

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CATSPER4 | c.718G>A p.V240M | Missense Mutation (SNP) | VAF 68/918 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.5); catalogued as rs745607033, COSV58794983; called by muse, mutect2
- FAT3 | c.6559G>C p.D2187H | Missense Mutation (SNP) | VAF 395/790 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53125259; called by muse, mutect2, varscan2
- PLPP3 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 44/594 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749957963, COSV64838909; called by muse, mutect2
- SEMA4B | c.2215C>T p.R739W | Missense Mutation (SNP) | VAF 185/452 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs201550724, COSV100153378, COSV60172897; called by muse, mutect2, varscan2
- USO1 | c.1553A>G p.N518S | Missense Mutation (SNP) | VAF 194/742 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.216); catalogued as rs753889836; called by muse, mutect2
- CA8 | c.863C>G p.A288G | Missense Mutation (SNP) | VAF 89/341 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HJV | c.1166del p.P389Qfs*3 (on ENST00000336751 / NM_213653.4; = p.P276Qfs*3 on NM_145277.5) | Frame Shift Del (DEL) | VAF 179/437 reads (41%) | called by mutect2, pindel, varscan2
- KIF1B | c.4805G>A p.G1602D (on ENST00000377086 / NM_001365952.1; = p.G1556D on NM_015074.3) | Missense Mutation (SNP) | VAF 58/570 reads (10%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- RCN2 | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 42/1226 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLC22A6 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 223/491 reads (45%) | SIFT tolerated (0.43); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- UQCRC1 | c.578A>T p.Q193L | Missense Mutation (SNP) | VAF 242/573 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, varscan2
- ARHGAP21 | c.1131G>A p.S377= | Silent (SNP) | VAF 146/911 reads (16%) | catalogued as rs768707165; called by muse, mutect2, varscan2
- CCDC171 | c.1470C>T p.D490= | Silent (SNP) | VAF 277/694 reads (40%) | called by muse, mutect2, varscan2
- CELF1 | c.807T>A p.A269= (on ENST00000358597 / NM_001376422.1; = p.A265= on NM_006560.4 and 10 other RefSeq transcripts) | Silent (SNP) | VAF 14/280 reads (5%) | catalogued as rs1167537044; called by muse, mutect2
- POTEM | c.297C>A p.G99= | Silent (SNP) | VAF 164/810 reads (20%) | catalogued as COSV101304490, COSV101304620; called by mutect2, varscan2
- SCIN | c.780C>T p.S260= (on ENST00000297029 / NM_001112706.3; = p.S13= on NM_033128.3) | Silent (SNP) | VAF 89/956 reads (9%) | called by muse, mutect2
- HNRNPD | c.460-12C>G | Intron (SNP) | VAF 253/882 reads (29%) | called by muse, mutect2, varscan2
